Gene-level copy-number profile of tumor specimen HTMCP-03-06-02012-01A from CGCI case HTMCP-03-06-02012, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 54.1 years (19,742 days).
Specimen HTMCP-03-06-02012-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7e554dc4-4431-42d6-8876-1a4430393358.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02012-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/6e544235-ecca-4300-8348-74ccacfed3f5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 963; copy number 2: 48,152; copy number 3: 7,044; copy number 4: 755; copy number 5: 814; copy number 6: 671.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:32,116,700–32,116,997, 1 gene (within-gene range 0–1): AC142381.2.
- chr16:32,262,827–32,279,115, 2 genes: AC133485.2, AC140878.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,485 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:158,732,198–198,123,232, 680 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 5–6 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 5: TRGC2.
- chr7:38,257,879–38,329,643, 11 genes, copy number 5: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2.
- chr9:126,326,829–126,507,041, 1 gene, copy number 5 (within-gene range 3–5): MVB12B.
- chr9:126,426,893–127,906,022, 43 genes, copy number 5: SNORD116, AL356309.2, AL356309.3, AL356309.1, AL161908.1, LMX1B, AL161908.2, ZBTB43, ZBTB34, RALGPS1, ANGPTL2, AL450263.1, GARNL3, AL450263.2, AL445222.1, SLC2A8, ZNF79, RPL12, SNORA65, LRSAM1, Y_RNA, NIBAN2, STXBP1, AL162426.1, PTRH1, MIR3911, CFAP157, TTC16, TOR2A, SH2D3C, AL162586.2, CDK9, MIR3960, MIR2861, FPGS, ENG, AL162586.1, Y_RNA, RNA5SP296, AK1, AL157935.2, MIR4672, ST6GALNAC6.
- chr9:134,025,481–134,943,207, 29 genes, copy number 5: BRD3OS, BRD3, AL445931.1, ARF4P1, BX649632.1, WDR5, RNU6ATAC, BX649601.1, LINC02247, AL354796.1, RXRA, MIR4669, AL669970.1, AL669970.3, AL669970.2, COL5A1, COL5A1-AS1, AL645768.1, MIR3689C, MIR3689A, MIR3689D1, MIR3689B, MIR3689D2, MIR3689E, MIR3689F, AL603650.1, FCN2, FCN1, AL353611.1.
- chr14:22,123,318–22,482,959, 40 genes, copy number 5: TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.

Autosomal genes at a single copy (total copy number 1): 948. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
